Surgical pathology report (de-identified scan), TCGA case TCGA-AL-3471, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AL-3471-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right Kidney Mass

Source of Specimen(s):

right Kidney resection with Adrenal gland

Gross Description:

Received in one part.

Source of Tissue: 1. Labeled #1, "right kidney"

Frozen Section Diagnosis: 1FS- PAPILLARY RENAL CELL CARCINOMA PER [REDACTED]

Gross Description: Received fresh labeled ", right kidney". It consists of a 460 gram right nephrectomy consisting of a kidney measuring 10.5 x 6 x 6 cm and perinephric fat measuring from 1 up to 5 cm from point of attachment. Dissection through the fat discloses no lesions, masses or nodal tissue. There is an area of fullness in the lower pole of the nephrectomy. At the hilum there is a 0.5 cm of ureter. The right ureter is opened and has a pin point lumen. The vascular margin is also unremarkable. The kidney is bivalved disclosing a soft predominantly necrotic mass in the lower pole that measures 4.4 x 3.5 x 3.5 cm. The lesion compresses the inferior calyx. The tumor is soft, necrotic, brownish-orange in color and towards the periphery there is some more solid possible viable lesion. Representative sections from areas to include possible lesion is submitted for frozen section in 1FS. The capsule and fat overlying the tumor are intact with no areas suspicious for invasion. Elsewhere the parenchyma is normal with the usual cortico-medullary junction present. Gross Photographs are Taken.

Designation of Sections: 1A- vascular and ureter margin, 1B- tumor in relationship to calyceal system, 1C-1E- tumor, 1F-1G- tumor with overlying fascia and capsule, 1H- uninvolved right kidney, 1I- perinephric fat

Note: Tissue is procured and sent for Cytogenetic Studies.

Final Diagnosis:

1. Right kidney:

- Low grade papillary renal cell carcinoma (type 1).
- 4.4 cm tumor is limited to kidney.
- No lymphovascular invasion is identified.
- Margins are negative for tumor.

[page 2 of 2]
- No lymph nodes are identified.
- Uninvolved kidney shows scattered globally sclerotic glomeruli.
- pT1bNxMx

Procedures/Addenda

FC Cytogenetics Solid Tumor

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Papillary Renal Cell Carcinoma

KARYOTYPE: Abnormal karyotype: 42
46,X,-Y,+2,+3,-4,+8,+16,+17,+20[cp9]
One cell also contained an extra copy of
chromosome 7 among other numerical changes.

RESULTS: The renal mass was harvested after seven and nine days in culture. Only nine metaphases could be found in a scan of ten slides. The chromosomes from these metaphases were counted and analyzed, and four of the metaphases were karyotyped by G-banding. All the cells contained numerical chromosome abnormalities that are listed in the karyotypic description above. The extra copies of chromosomes 16, 17, and 20 and the missing [REDACTED] chromosome have all been reported in papillary renal cell carcinoma (PRCC). Although only one cell contained an extra copy of chromosome 7, this is a significant finding in PRCC.

Source: NCI Genomic Data Commons file b0cf7455-4ca2-4196-9742-a26136d2707e (TCGA-AL-3471.E67AEAD5-6785-4177-B9A1-B0E4163B4F36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).